FM case AD11411 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/56861fee-5fb3-4268-8cdc-d356f1371f5f

Female, 52.7 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the head, face or neck; specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
